Gene-level copy-number profile of tumor specimen TCGA-AX-A1C8-01A from TCGA case TCGA-AX-A1C8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.9 years (28,452 days).
Specimen TCGA-AX-A1C8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.b19b999a-5d30-4fc8-a522-1c19c433caf6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A1C8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5bd0951e-601e-45fa-9282-5e4b4e652cc1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,946; copy number 2: 43,740; copy number 3: 3,965; copy number 4: 2,461; copy number 5: 554; copy number 6: 41; copy number 8: 96.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A1C8-01A-11D-A134-01): tumor purity 0.74, ploidy 4.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 691 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:29,236,516–29,709,547, 4 genes, copy number 6 (within-gene range 1–6): PTPRU, LINC01756, AL671862.1, AC092265.1.
- chr1:150,560,895–152,196,699, 96 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr5:176,726,942–177,300,213, 9 genes, copy number 5 (within-gene range 3–5): AC113391.2, LINC01574, UNC5A, HK3, UIMC1, ZNF346, ZNF346-IT1, FGFR4, NSD1.
- chr6:135,851,701–136,195,574, 1 gene, copy number 6 (within-gene range 4–6): PDE7B.
- chr6:135,991,936–145,964,423, 147 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr16:65,580,668–66,412,135, 8 genes, copy number 5: AC092138.2, AC092138.1, AC022164.1, AC025281.1, RNA5SP428, AC012325.1, CDH5, LINC00920.
- chr17:57,771,946–63,427,699, 186 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:67,377,281–67,697,261, 1 gene, copy number 5 (within-gene range 4–5): PITPNC1.
- chr17:67,524,481–72,640,472, 86 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:14,380,501–17,026,815, 145 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:32,719,753–32,978,229, 8 genes, copy number 6 (within-gene range 4–6): TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24.

Autosomal genes at a single copy (total copy number 1): 8,946. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
